Somatic mutation profile of tumor specimen TCGA-93-8067-01C (aliquot TCGA-93-8067-01C-01D-A38P-08) from TCGA case TCGA-93-8067, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 77.9 years (28,453 days).
Specimen TCGA-93-8067-01C: Sample type: FFPE Scrolls; Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3497b579-9a79-4507-94f8-d6f99ef06327.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-93-8067-10A (Blood Derived Normal), aliquot TCGA-93-8067-10A-01D-2284-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc865108-ace4-4af8-87bc-ad7b3f7b0d2a

The open-access MAF lists 289 somatic variants for this specimen: 208 protein-altering or splice-affecting, 76 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 178, Silent 76, Nonsense Mutation 20, Splice Site 5, Frame Shift Del 3, Intron 2, RNA 2, Splice Region 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GCK | c.824G>T p.R275L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.318); catalogued as rs767565869, COSV100357249, COSV60787127; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 14/91 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- NFE2L2 | c.70T>C p.W24R | Missense Mutation (SNP) | VAF 14/55 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1328994103, COSV67960091, COSV67960815, COSV67963035; called by muse, mutect2, varscan2
- AARS2 | c.2305C>T p.R769C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs140918846; called by mutect2, varscan2
- ADAM22 | c.2158G>C p.D720H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.14); catalogued as COSV99717188; called by muse, mutect2, varscan2
- ADCY5 | c.1401C>A p.N467K | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV100567820, COSV59194839; called by muse, mutect2
- ALMS1 | c.3769C>T p.H1257Y | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as COSV100042679; called by muse, varscan2
- ANK2 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1474105619, COSV52152842; called by muse, mutect2, varscan2
- ANKMY1 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs768966375, COSV56030766; called by muse, mutect2, varscan2
- ANO6 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100263347; called by muse, mutect2
- APOB | c.6139G>A p.E2047K | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.115); catalogued as COSV99266011; called by muse, mutect2, varscan2
- APPL2 | c.797C>G p.S266C | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.191); catalogued as COSV99314854; called by muse, mutect2, varscan2
- ARHGAP6 | c.1088C>T p.S363L | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100272988; called by muse, mutect2, varscan2
- ARHGEF18 | c.591G>C p.K197N (on ENST00000359920 / NM_001130955.2; = p.K93N on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as COSV100149595; called by muse, mutect2
- ASCC2 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100316306; called by muse, mutect2, varscan2
- ATXN7L1 | c.321G>C p.Q107H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.24); catalogued as COSV100596886; called by muse, mutect2, varscan2
- B2M | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | catalogued as COSV62563917; called by muse, mutect2, varscan2
- B2M | c.266A>G p.E89G | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV100837670; called by muse, mutect2, varscan2
- B3GALT4 | c.602G>C p.R201T | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.229); catalogued as COSV101005646; called by muse, mutect2
- BCAN | c.2183C>A p.T728K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100228173; called by muse, varscan2
- BCL3 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV99378191; called by muse, mutect2, varscan2
- BOD1L1 | c.3309G>T p.Q1103H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV99239546; called by muse, mutect2, varscan2
- BPHL | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV100984488, COSV66744112; called by muse, mutect2
- BPTF | c.3451G>C p.E1151Q | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV100075117; called by muse, mutect2, varscan2
- C11orf1 | c.344-1G>T p.X115_splice | Splice Site (SNP) | VAF 12/48 reads (25%) | catalogued as rs145116726, COSV99499970; called by muse, varscan2
- C2CD5 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs1230288897, COSV100448633, COSV100448815; called by muse, mutect2
- C8orf76 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374975138, COSV99414859; called by muse, mutect2, varscan2
- CCDC70 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV54430525, COSV99665370; called by muse, mutect2
- CD163L1 | c.3996G>C p.Q1332H | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.055); catalogued as COSV100550158; called by muse, mutect2
- CD209 | c.714C>G p.I238M | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.609); catalogued as rs1356104625, COSV99214041; called by muse, varscan2
- CD47 | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.166); catalogued as rs1308525788, COSV100790124; called by muse, mutect2, varscan2
- CEMIP2 | c.2377G>C p.D793H | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV100987404; called by muse, mutect2
- CEP104 | c.892-1G>C p.X298_splice | Splice Site (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100986634; called by muse, mutect2, varscan2
- CGREF1 | c.103C>G p.Q35E | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV99565196; called by mutect2, varscan2
- CHEK2 | c.46A>C p.S16R | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.069); catalogued as rs1426424086, COSV100101834; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLIP1 | c.4199C>T p.S1400L (on ENST00000620786 / NM_001247997.1; = p.S1389L on NM_002956.2) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs965447390, COSV100211850; called by mutect2, varscan2
- CMTR2 | c.337C>G p.Q113E | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100579196, COSV57602503; called by muse, mutect2
- CNTN3 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as rs1350870526, COSV55173355; called by muse, mutect2, varscan2
- COL16A1 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV99594644; called by muse, mutect2, varscan2
- COP1 | c.1162C>G p.Q388E | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.585); catalogued as rs1474592774, COSV100443400; called by muse, mutect2, varscan2
- CRIM1 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.965); catalogued as COSV54868671, COSV99753574; called by muse, mutect2, varscan2
- CSMD3 | c.5231del p.G1744Efs*49 (on ENST00000297405 / NM_001363185.1; = p.G1640Efs*49 on NM_052900.3) | Frame Shift Del (DEL) | VAF 15/113 reads (13%) | catalogued as COSV52146370, COSV99822288; called by mutect2, pindel, varscan2
- CXCL12 | c.122G>A p.R41K | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1348700155, COSV100638951; called by muse, mutect2, varscan2
- DCBLD1 | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as rs1186229621, COSV99757699; called by muse, mutect2, varscan2
- DCDC1 | c.3061C>A p.Q1021K (on ENST00000597505 / NM_001367979.1; = p.Q128K on NM_020869.3) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1409688921, COSV100338372; called by muse, mutect2, varscan2
- DCLRE1A | c.233C>G p.S78C | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV100800387; called by muse, mutect2, varscan2
- DFFB | c.710C>G p.S237* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100138712, COSV58860672; called by mutect2, varscan2
- DGCR8 | c.1596C>G p.F532L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV100707998, COSV61226317; called by mutect2, varscan2
- DHRS7 | c.973-1G>A p.X325_splice | Splice Site (SNP) | VAF 12/170 reads (7%) | catalogued as COSV99381626; called by muse, mutect2
- DIO2 | c.544G>T p.V182L | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.484); catalogued as COSV101375894; called by muse, mutect2, varscan2
- DNAH12 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100244584, COSV60857296; called by muse, mutect2, varscan2
- DNAH5 | c.3625G>A p.E1209K | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV54263582; called by muse, mutect2
- DZIP1L | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs987675067, COSV59521667; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.715G>C p.D239H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100349210; called by muse, mutect2, varscan2
- EMC4 | c.518G>C p.R173T | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV50784678, COSV99272275; called by muse, mutect2, varscan2
- EPS15 | c.651G>T p.T217= | Splice Region (SNP) | VAF 6/98 reads (6%) | catalogued as rs1474368057, COSV100869555; called by muse, mutect2
- ERP44 | c.1150G>C p.E384Q | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV99316481; called by muse, mutect2
- EXOC1 | c.467T>C p.V156A | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1283559253, COSV100637899; called by muse, mutect2
- EXOSC10 | c.1343A>G p.Y448C | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100442606; called by muse, mutect2, varscan2
- F5 | c.3835G>A p.D1279N | Missense Mutation (SNP) | VAF 20/305 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.08); catalogued as COSV100889130; called by muse, mutect2
- FAM47B | c.1842G>T p.K614N | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV100264378; called by muse, mutect2, varscan2
- FMO1 | c.224C>A p.P75Q | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100707803; called by muse, mutect2, varscan2
- FRYL | c.6281C>G p.P2094R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV99977114; called by muse, mutect2
- FRYL | c.4069G>T p.G1357* | Nonsense Mutation (SNP) | VAF 10/122 reads (8%) | catalogued as COSV51952221, COSV99977118; called by muse, mutect2
- FZD2 | c.1280G>A p.G427D | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59528334; called by muse, mutect2, varscan2
- GIGYF1 | c.848G>A p.G283D | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99309535; called by muse, mutect2, varscan2
- GLIPR1L2 | c.348T>G p.I116M | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100248628; called by muse, mutect2, varscan2
- GNRHR | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV99892205; called by muse, mutect2, varscan2
- GPR15 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as COSV99423784; called by muse, mutect2, varscan2
- GPR75 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.055); catalogued as rs748159475, COSV100766142; called by muse, mutect2, varscan2
- HOXD3 | c.355C>A p.P119T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.908); catalogued as rs1361097280, COSV99980212; called by muse, mutect2
- IGHMBP2 | c.873G>C p.Q291H | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as rs748408625, COSV99662146; called by muse, mutect2, varscan2
- ILDR2 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.895); catalogued as COSV99613047, COSV99613986; called by muse, mutect2, varscan2
- IMPA2 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 10/152 reads (7%) | catalogued as COSV99302598; called by muse, mutect2
- IRF2BPL | c.92C>G p.S31W | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as rs1425872953, COSV99468190; called by muse, mutect2
- ITIH5 | c.296C>A p.T99N | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99904856; called by muse, mutect2, varscan2
- IZUMO1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as COSV99710848; called by muse, mutect2, varscan2
- JPH1 | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.021); catalogued as COSV100646640; called by muse, mutect2, varscan2
- KIAA0586 | c.3626C>G p.S1209* (on ENST00000619416 / NM_001244190.2; = p.S1148* on NM_014749.5) | Nonsense Mutation (SNP) | VAF 5/55 reads (9%) | catalogued as COSV99708281; called by muse, mutect2, varscan2
- KIF27 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99927033; called by muse, mutect2, varscan2
- KL | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 28/215 reads (13%) | catalogued as COSV101199070; called by muse, mutect2, varscan2
- KLHL9 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100757109; called by muse, mutect2, varscan2
- KRT3 | c.1106G>T p.S369I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100527114; called by muse, mutect2, varscan2
- LCOR | c.302C>A p.S101Y | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100603654; called by muse, mutect2, varscan2
- LENG1 | c.483G>T p.Q161H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV99651956; called by muse, mutect2, varscan2
- LGR5 | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99878016; called by muse, mutect2
- LIPE | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1233388425, COSV54925671; called by muse, mutect2, varscan2
- LRFN5 | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV53246426, COSV99982062, COSV99984147; called by mutect2, varscan2
- LRP1B | c.11527G>A p.E3843K | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.081); catalogued as COSV101257741; called by muse, mutect2
- LRRC37A3 | c.3397G>C p.D1133H | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58535039, COSV58536353; called by muse, mutect2
- LRRC7 | c.2317G>A p.D773N (on ENST00000651989 / NM_001370785.2; = p.D740N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); catalogued as COSV99227474; called by muse, mutect2, varscan2
- LSR | c.728C>G p.S243* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as COSV100670479; called by muse, mutect2, varscan2
- MAGEC3 | c.696C>G p.F232L | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.168); catalogued as COSV100025537; called by muse, mutect2, varscan2
- MCF2L2 | c.2329G>C p.D777H | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100192790; called by muse, mutect2, varscan2
- MDC1 | c.3166C>G p.Q1056E | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV100902410, COSV100902854; called by muse, mutect2
- MFF | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.538); catalogued as COSV100449342; called by muse, mutect2
- MGAT4C | c.1093G>C p.D365H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as COSV59837639; called by muse, mutect2
- MOB1B | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100511567, COSV58675594; called by muse, mutect2
- MTBP | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs1185537104, COSV100012214; called by muse, mutect2, varscan2
- MTUS2 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV70915080; called by muse, mutect2
- MUC16 | c.9659T>A p.I3220N | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV101200122; called by muse, mutect2, varscan2
- MUC17 | c.113G>C p.G38A | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV100073701; called by muse, mutect2, varscan2
- MYH3 | c.3316C>G p.Q1106E | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV99878315; called by muse, mutect2
- NAV2 | c.2230G>T p.A744S (on ENST00000396087 / NM_001244963.2; = p.A721S on NM_145117.5) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.101); catalogued as COSV100586460; called by muse, mutect2, varscan2
- NFRKB | c.811C>G p.Q271E (on ENST00000446488 / NM_001143835.2; = p.Q296E on NM_006165.3) | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.542); catalogued as COSV100451939; called by muse, mutect2
- NIPBL | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV99240920; called by muse, mutect2, varscan2
- NLN | c.799G>C p.A267P | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101114320; called by muse, mutect2
- NRK | c.3797C>T p.S1266L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99687488, COSV99688076; called by muse, mutect2
- NTNG1 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV53964876, COSV99637837; called by muse, mutect2, varscan2
- NUCB2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as COSV100082829; called by muse, mutect2
- NUFIP1 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.706); catalogued as rs1467418967, COSV100998010; called by muse, mutect2, varscan2
- OAS2 | c.2039G>T p.W680L | Missense Mutation (SNP) | VAF 13/229 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60802391, COSV60804741; called by muse, mutect2
- OPRM1 | c.1105C>A p.R369S | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV100001511, COSV57674181; called by muse, mutect2, varscan2
- OR10Z1 | c.170C>G p.T57S | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV100779031; called by muse, mutect2, varscan2
- OR2T35 | c.618G>T p.M206I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100442295; called by mutect2, varscan2
- OR4C3 | c.866A>T p.N289I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100167913; called by muse, mutect2, varscan2
- PATJ | c.5119G>T p.A1707S | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); catalogued as rs749949716, COSV100957214; called by mutect2, varscan2
- PAX1 | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767792155, COSV68273467; called by mutect2, varscan2
- PCDHA12 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.558); catalogued as COSV56530538; called by muse, mutect2
- PCDHA6 | c.1615G>T p.D539Y | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100971530, COSV65348503; called by muse, mutect2, varscan2
- PDE3B | c.1086G>T p.M362I | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as COSV99962673; called by muse, mutect2, varscan2
- PDLIM5 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs778323849, COSV100523807; called by mutect2, varscan2
- PDZD2 | c.8473G>C p.E2825Q | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99225348; called by muse, mutect2
- PDZRN3 | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.666); catalogued as COSV99730088; called by muse, mutect2
- PER3 | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100728371, COSV62706829; called by mutect2, varscan2
- PHF14 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.271); catalogued as COSV101301815; called by muse, mutect2, varscan2
- PHF3 | c.449C>G p.S150* | Nonsense Mutation (SNP) | VAF 24/200 reads (12%) | catalogued as COSV100012794; called by muse, mutect2, varscan2
- PIK3AP1 | c.1864G>A p.V622M | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV100225850; called by muse, mutect2
- PLBD2 | c.705C>G p.I235M | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs1299738077, COSV99785356; called by muse, mutect2, varscan2
- PLD5 | c.973G>C p.D325H (on ENST00000442594; = p.D263H on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100140721, COSV59173237; called by muse, mutect2
- PNRC1 | c.175C>G p.H59D | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.215); catalogued as COSV100259933; called by muse, mutect2, varscan2
- PPP1CC | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100534886; called by muse, mutect2, varscan2
- PPP1R13B | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV99159534; called by muse, mutect2
- PRKDC | c.2632G>T p.E878* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as rs1319344777, COSV100041008; called by muse, mutect2, varscan2
- PRPF38A | c.241C>G p.Q81E | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV57123410, COSV99933322; called by muse, mutect2
- PRPF40B | c.2230G>A p.E744K (on ENST00000380281; = p.E731K on NM_012272.3) | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.034); catalogued as COSV99526426; called by muse, mutect2, varscan2
- PSG6 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 34/307 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as COSV99414133; called by muse, varscan2
- RAD51AP1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.056); catalogued as COSV99961315; called by muse, mutect2, varscan2
- RBL2 | c.1093C>T p.L365F | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100043423, COSV100043717; called by muse, mutect2, varscan2
- RBMXL1 | c.1166G>C p.R389T | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV99556379; called by muse, mutect2, varscan2
- RCN2 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100312789; called by muse, mutect2, varscan2
- RECQL5 | c.2602C>T p.Q868* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100512044; called by muse, mutect2, varscan2
- RELCH | c.3460G>T p.V1154F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV99902220; called by muse, mutect2, varscan2
- RFC4 | c.974C>G p.S325C | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV99961243, COSV99961450; called by muse, mutect2
- RGS22 | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 11/132 reads (8%) | catalogued as rs932703758, COSV100693330, COSV62665175; called by muse, mutect2
- RIPOR3 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV50385525; called by muse, varscan2
- RNF111 | c.878C>G p.S293* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100789082; called by muse, mutect2, varscan2
- RRP36 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1369251295, COSV99763788; called by muse, varscan2
- RSL1D1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100851990, COSV100852018; called by muse, mutect2, varscan2
- RTN4IP1 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV100954197; called by muse, mutect2, varscan2
- SASH3 | c.592-1G>A p.X198_splice | Splice Site (SNP) | VAF 11/71 reads (15%) | catalogued as COSV100795240; called by muse, mutect2, varscan2
- SCAMP2 | c.785C>G p.S262* | Nonsense Mutation (SNP) | VAF 18/150 reads (12%) | catalogued as COSV51510435; called by muse, mutect2, varscan2
- SCN3A | c.5371G>A p.E1791K | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99327283; called by muse, mutect2
- SEC23A | c.1519C>G p.Q507E | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.028); catalogued as COSV100305551; called by muse, mutect2, varscan2
- SERPINA9 | c.953T>A p.L318Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100098452; called by muse, mutect2, varscan2
- SETDB2 | c.395G>C p.R132T | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.108); catalogued as rs1273692027, COSV99320818; called by muse, mutect2
- SETX | c.3691G>A p.E1231K | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99809999; called by muse, mutect2
- SETX | c.3124G>C p.E1042Q | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV99810002; called by muse, mutect2
- SIGIRR | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV100230104; called by muse, mutect2, varscan2
- SLC19A2 | c.907G>T p.A303S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs867139297, COSV99356990; called by muse, mutect2, varscan2
- SLC35G2 | c.560C>G p.S187* | Nonsense Mutation (SNP) | VAF 11/99 reads (11%) | catalogued as COSV101262040; called by muse, mutect2, varscan2
- SLC39A3 | c.585G>C p.E195D | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99514217; called by muse, mutect2, varscan2
- SOX6 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100322364; called by muse, mutect2, varscan2
- SPINDOC | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs759066744, COSV99588692; called by muse, mutect2, varscan2
- STAB2 | c.7135C>A p.H2379N | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV101186036; called by muse, mutect2
- STAT1 | c.340A>G p.K114E | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.088); catalogued as COSV100738686; called by muse, mutect2
- STYXL2 | c.1644G>C p.K548N | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99609368; called by muse, mutect2
- SVEP1 | c.3973C>A p.Q1325K | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.093); catalogued as COSV100238209; called by muse, mutect2, varscan2
- SYNE1 | c.4592G>A p.R1531K (on ENST00000367255 / NM_182961.4; = p.R1538K on NM_033071.3) | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV99567081; called by muse, mutect2
- SYNE2 | c.12149A>G p.N4050S | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100647849; called by muse, mutect2, varscan2
- TAGLN2 | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV100231177; called by muse, mutect2
- TDRD1 | c.2975G>C p.R992T | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.426); catalogued as COSV99314641; called by muse, mutect2, varscan2
- TDRD10 | c.87C>G p.F29L | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100873124; called by muse, mutect2
- THBS1 | c.2886G>A p.M962I | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as COSV99528007; called by muse, mutect2, varscan2
- TLR4 | c.2126A>G p.Y709C (on ENST00000355622 / NM_138554.5; = p.Y669C on NM_003266.4) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs377719663, COSV100842777; called by mutect2, varscan2
- TMEM131L | c.2545C>G p.L849V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99547584; called by muse, mutect2, varscan2
- TPP2 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV101060295; called by muse, mutect2, varscan2
- TRERF1 | c.3493G>A p.D1165N | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.238); catalogued as rs769439387, COSV61674127; called by muse, mutect2, varscan2
- TRIM62 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.724); catalogued as COSV99357823; called by muse, mutect2
- TRIO | c.6024G>C p.M2008I | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.071); catalogued as COSV100709729, COSV100710467; called by muse, mutect2
- TRIP4 | c.1471C>G p.L491V | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV56029327; called by muse, mutect2, varscan2
- TRMT10A | c.53del p.K18Sfs*4 | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | catalogued as rs747549755; called by mutect2, pindel, varscan2
- TTC17 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99235429; called by muse, mutect2, varscan2
- TTC27 | c.1237C>T p.L413F | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100513154; called by muse, mutect2, varscan2
- TTN | c.64990G>C p.D21664H (on ENST00000591111; = p.D14240H on NM_003319.4) | Missense Mutation (SNP) | VAF 7/77 reads (9%) | PolyPhen benign (0.001); catalogued as COSV100616664, COSV60045919; called by muse, mutect2
- TUBGCP3 | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV99996947; called by muse, mutect2, varscan2
- UBAP2 | c.560C>G p.S187* | Nonsense Mutation (SNP) | VAF 15/198 reads (8%) | catalogued as COSV100671530, COSV100672031; called by muse, mutect2
- UBE2C | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99708633; called by mutect2, varscan2
- UBE2E3 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.487); catalogued as COSV101150421, COSV101150714; called by muse, mutect2, varscan2
- UGT8 | c.114C>A p.F38L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.122); catalogued as COSV100179237; called by muse, mutect2
- USP20 | c.731A>G p.H244R | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100204393; called by muse, mutect2, varscan2
- USP9Y | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as rs888918343, COSV100168365; called by muse, mutect2, varscan2
- XRCC6 | c.1672G>C p.E558Q | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as COSV100777847; called by muse, mutect2, varscan2
- YARS1 | c.75G>T p.E25D | Missense Mutation (SNP) | VAF 27/370 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100993438; called by muse, mutect2
- ZC3H7A | c.2213+2T>C p.X738_splice | Splice Site (SNP) | VAF 9/129 reads (7%) | catalogued as COSV100865539; called by muse, mutect2
- ZFP69B | c.1211G>A p.R404K | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as COSV100848268; called by muse, mutect2, varscan2
- ZNF135 | c.547G>A p.E183K (on ENST00000313434 / NM_001289401.2; = p.E195K on NM_003436.4) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.201); catalogued as rs768046446, COSV100536641; called by mutect2, varscan2
- ZNF202 | c.38G>T p.W13L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.968); catalogued as COSV100279064; called by muse, mutect2, varscan2
- ZNF221 | c.1402C>T p.H468Y | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52111145; called by muse, mutect2, varscan2
- ZNF507 | c.2403G>C p.L801F | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100321884; called by muse, mutect2
- ZNF574 | c.1054G>C p.D352H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV99726194; called by muse, mutect2, varscan2
- ZNF7 | c.932G>A p.C311Y | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773588606, COSV100295911; called by muse, mutect2, varscan2
- ZNF766 | c.63G>C p.E21D | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100765362; called by muse, mutect2, varscan2
- ZNF831 | c.3018G>C p.E1006D | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV100926068; called by mutect2, varscan2
- ZNRF4 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs541728675, COSV99706564; called by mutect2, varscan2
- CWC25 | c.365C>G p.S122* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- GGNBP2 | c.1912G>A p.D638N | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); called by muse, mutect2
- OR4N2 | c.215_216del p.S72Lfs*49 | Frame Shift Del (DEL) | VAF 37/288 reads (13%) | called by mutect2, varscan2
- ACO2 | c.1455G>A p.E485= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs1237483884, COSV99347476; called by muse, mutect2, varscan2
- ACSL1 | c.1170G>A p.L390= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV99860698; called by muse, mutect2
- AGBL1 | c.2721G>A p.K907= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV101223314; called by muse, mutect2, varscan2
- ARHGEF19 | c.2232G>A p.V744= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV99580525; called by muse, mutect2
- BAD | c.420G>A p.Q140= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs368322510; called by mutect2, varscan2
- BAG6 | c.3252C>T p.L1084= (on ENST00000676571; = p.L1037= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99277161; called by muse, mutect2
- BCAN | c.2184A>C p.T728= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV100228174; called by muse, varscan2
- CCNB3 | c.3153C>G p.P1051= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV99328687, COSV99329215; called by muse, mutect2, varscan2
- CD180 | c.414C>A p.S138= | Silent (SNP) | VAF 21/186 reads (11%) | catalogued as COSV99842275; called by muse, mutect2
- CD4 | c.228G>A p.L76= | Silent (SNP) | VAF 20/226 reads (9%) | catalogued as COSV50596877; called by muse, mutect2
- CHD3 | c.1251A>G p.K417= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV100391284, COSV57880318; called by muse, mutect2, varscan2
- CHRNA2 | c.783C>T p.I261= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV99532282; called by muse, mutect2, varscan2
- CHST9 | c.1146G>A p.Q382= | Silent (SNP) | VAF 15/127 reads (12%) | catalogued as COSV99410259; called by muse, mutect2, varscan2
- CMTR1 | c.987G>A p.G329= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV100990880; called by muse, mutect2
- COL6A3 | c.2116C>T p.L706= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99798800; called by muse, mutect2, varscan2
- DCLRE1A | c.2403C>T p.L801= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV100800385; called by mutect2, varscan2
- DDB2 | c.888C>T p.F296= | Silent (SNP) | VAF 15/126 reads (12%) | catalogued as rs1190260071, COSV99921669; called by muse, mutect2, varscan2
- DNAH11 | c.5907C>T p.I1969= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100179463; called by muse, mutect2
- DOCK7 | c.6369C>T p.V2123= (on ENST00000635253 / NM_001367561.1; = p.V2092= on NM_033407.3) | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV99224756; called by muse, mutect2
- ERAP1 | c.228C>T p.F76= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as COSV99701004; called by muse, mutect2, varscan2
- ETV3 | c.21C>T p.I7= | Silent (SNP) | VAF 13/283 reads (5%) | catalogued as rs1007124749, COSV100461084; called by muse, mutect2
- FEZ1 | c.351C>G p.L117= | Silent (SNP) | VAF 8/134 reads (6%) | catalogued as COSV99630732; called by muse, mutect2
- FOXL2 | c.258G>A p.A86= | Silent (SNP) | VAF 16/156 reads (10%) | catalogued as rs1487527950, COSV100374601; called by muse, mutect2, varscan2
- FRYL | c.7881G>A p.L2627= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV51953140; called by muse, mutect2, varscan2
- GAS2L2 | c.2265G>A p.L755= | Silent (SNP) | VAF 23/127 reads (18%) | called by muse, mutect2, varscan2
- GINS4 | c.219G>A p.L73= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs560085005, COSV99394558; called by muse, mutect2, varscan2
- HERC2 | c.2007C>T p.S669= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV99874357; called by muse, mutect2, varscan2
- HIVEP2 | c.5997G>A p.Q1999= | Silent (SNP) | VAF 22/164 reads (13%) | catalogued as COSV99173767; called by muse, mutect2, varscan2
- ITLN2 | c.537G>A p.L179= | Silent (SNP) | VAF 13/153 reads (8%) | catalogued as COSV100600722; called by muse, mutect2
- KCNH7 | c.2748C>A p.T916= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV100148258; called by muse, mutect2
- KCNS2 | c.342C>T p.F114= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV99751212; called by muse, mutect2, varscan2
- KIF20A | c.1119C>G p.L373= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV99137086; called by muse, mutect2
- KMT2D | c.14982G>T p.L4994= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as rs1325810003, COSV99982718; called by muse, mutect2
- MAML1 | c.979C>T p.L327= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV52988565; called by muse, mutect2, varscan2
- MARS2 | c.21C>T p.L7= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs925365571, COSV99986603; called by muse, mutect2, varscan2
- MDC1 | c.345G>C p.L115= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100902855, COSV64526555; called by muse, mutect2, varscan2
- METAP1D | c.57C>T p.F19= | Silent (SNP) | VAF 22/159 reads (14%) | catalogued as rs764314956, COSV59932073; called by muse, mutect2, varscan2
- MTHFR | c.414C>T p.I138= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV100411989; called by muse, mutect2
- MVB12A | c.486C>G p.L162= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100396522; called by muse, varscan2
- MYH13 | c.4602G>A p.K1534= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99354244; called by muse, mutect2, varscan2
- NCAN | c.3837G>A p.R1279= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV99387424; called by muse, mutect2
- NELFCD | c.978C>T p.F326= (on ENST00000602795; = p.F308= on NM_198976.4) | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as rs368566687, COSV99413611; called by mutect2, varscan2
- NRP1 | c.1701G>A p.E567= | Silent (SNP) | VAF 12/133 reads (9%) | catalogued as COSV99588894; called by muse, mutect2
- NRXN3 | c.2451C>A p.I817= (on ENST00000335750 / NM_001330195.2; = p.I444= on NM_004796.6) | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs944771134, COSV100204533; called by muse, mutect2, varscan2
- NTRK2 | c.1119G>A p.Q373= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV99455767; called by mutect2, varscan2
- OR2Y1 | c.313C>T p.L105= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100322778; called by mutect2, varscan2
- PCDHB4 | c.633C>T p.L211= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV52019723; called by muse, mutect2, varscan2
- PDE3A | c.825G>A p.L275= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs750288734, COSV62967221; called by muse, mutect2, varscan2
- PDE6C | c.1638C>G p.T546= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV101008775; called by muse, mutect2, varscan2
- POLG2 | c.150C>T p.L50= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs1202762031, COSV99858037; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPIP5K1 | c.3582C>T p.F1194= (on ENST00000396923; = p.F1169= on NM_014659.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV100288719; called by muse, mutect2, varscan2
- PRDM15 | c.1215G>A p.Q405= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as COSV99520238; called by muse, mutect2
- PRELID3B | c.195G>A p.V65= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV100582263; called by muse, mutect2, varscan2
- RAB17 | c.612G>A p.A204= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs375159510; called by muse, mutect2, varscan2
- RNF213 | c.14872C>A p.R4958= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100300738, COSV60403650; called by muse, mutect2
- RTTN | c.21C>T p.I7= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV99732706; called by muse, mutect2, varscan2
- RUNX1T1 | c.12C>G p.V4= | Silent (SNP) | VAF 13/128 reads (10%) | catalogued as COSV56146531, COSV56155055, COSV99752575; called by muse, mutect2
- RYR3 | c.13236G>A p.L4412= (on ENST00000389232; = p.L4413= on NM_001036.6) | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs1240806955, COSV101212935; called by muse, mutect2
- SAMD12 | c.333G>T p.L111= | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as COSV100126179, COSV59053721; called by muse, mutect2, varscan2
- SEMA3F | c.831C>T p.F277= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV99137560; called by muse, mutect2, varscan2
- SERPINF2 | c.1380G>A p.L460= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV60665661; called by muse, mutect2, varscan2
- SIGLEC1 | c.2235C>T p.F745= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV52466462; called by muse, mutect2, varscan2
- SIGLEC8 | c.1320G>C p.G440= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100367285; called by mutect2, varscan2
- SLIT3 | c.1605C>T p.T535= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs1033096222, COSV60631830; called by muse, mutect2, varscan2
- SP140 | c.1869C>T p.F623= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV100613844; called by muse, mutect2
- STXBP6 | c.462C>T p.I154= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as COSV100121873, COSV60596633; called by muse, mutect2
- TAAR5 | c.15C>T p.F5= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV57799036; called by muse, mutect2, varscan2
- TC2N | c.390C>T p.F130= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100562945, COSV61747005; called by muse, mutect2
- TRIP10 | c.930C>T p.L310= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV100505168; called by mutect2, varscan2
- USP13 | c.1896C>A p.P632= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as rs377395498, COSV55863532; called by muse, mutect2, varscan2
- WDR90 | c.264C>G p.L88= | Silent (SNP) | VAF 22/344 reads (6%) | catalogued as COSV99553553; called by muse, mutect2
- YY1AP1 | c.1011C>T p.I337= (on ENST00000295566 / NM_139118.2; = p.I280= on NM_018253.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as COSV99804197; called by muse, mutect2
- ZBBX | c.739C>T p.L247= | Silent (SNP) | VAF 14/214 reads (7%) | catalogued as rs1220015618, COSV100284205, COSV56792438, COSV56800194; called by muse, mutect2
- ZNF343 | c.256C>T p.L86= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as rs1422337145, COSV99601453; called by muse, mutect2
- ZNF493 | c.270C>T p.A90= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as COSV100828729; called by muse, mutect2, varscan2
- ZNF574 | c.1512C>T p.F504= | Silent (SNP) | VAF 25/233 reads (11%) | catalogued as COSV99726196; called by muse, mutect2, varscan2
- ANKRD20A5P | n.240G>A | RNA (SNP) | VAF 23/293 reads (8%) | called by muse, mutect2
- DIO3 | chr14:101560306 G>A | 5'Flank (SNP) | VAF 4/30 reads (13%) | catalogued as rs1305123824; called by muse, mutect2
- MAPK10 | c.1138+101G>C | Intron (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- MIR182 | n.101C>T | RNA (SNP) | VAF 5/44 reads (11%) | catalogued as rs1199450627; called by muse, mutect2
- SUN1 | c.659-287G>T | Intron (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
